Somatic mutation profile of tumor specimen TCGA-AB-2939-03A (aliquot TCGA-AB-2939-03A-01W-0745-08) from TCGA case TCGA-AB-2939, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.6 years (26,512 days).
Specimen TCGA-AB-2939-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d851b29-eb9e-4873-aa33-4661d5f33c3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2939-11A (Solid Tissue Normal), aliquot TCGA-AB-2939-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e063c89-309b-413b-a1e8-5c3d2b06370f

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 126/280 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GALNT18 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs951723727, COSV57159478; called by muse, mutect2, varscan2
- KIAA1191 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); catalogued as COSV100055305; called by muse, mutect2
- POU3F2 | c.1284dup p.S429Efs*2 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | catalogued as rs775815466; called by pindel, varscan2
- TNNT2 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs45608937, CM087596, COSV99372078; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USHBP1 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV99394008; called by muse, mutect2
- KLHL31 | c.1715dup p.W573Lfs*84 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
